Surgical pathology report (de-identified scan), TCGA case TCGA-55-8085, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-8085-01A (Primary Tumor).

[page 1 of 4]
Results

GROSS AND MICROSCOPIC SURGICAL PANEL

Specimen Information

Collection Date and Time

Component Results

SURGICAL PANEL:

SURGICAL PATHOLOGY REPORT

Final Report

DIAGNOSIS

A) LYMPH NODE, LEVEL 9, LEFT, BIOPSY:

1. Benign lymph node
2. No evidence of metastatic carcinoma

B) LYMPH NODE, LEVEL 9, LEFT, BIOPSY:

1. Benign lymph node
2. No evidence of metastatic carcinoma

C) LUNG, LEFT LOWER LOBE, WEDGE RESECTION:

1. Moderately differentiated adenocarcinoma with papillary features forming a mass measuring 2.5 x 2.2 x 1.6 cm
2. Stapled parenchymal resection margin and visceral pleura free of involvement
3. Two benign peribronchial lymph nodes
4. Emphysematous changes are present in surrounding non-involved pulmonary parenchyma

D) LUNG, LEFT UPPER LOBE, WEDGE RESECTION:

1. Severe emphysematous changes with subpleural bullous formation
2. Apical fibrous scar
3. No evidence of active inflammation or neoplasia

E) LYMPH NODE, LEVEL 7, LEFT, BIOPSY:

1. Benign lymph node
2. No evidence of metastatic carcinoma

F) LYMPH NODE, LEVEL 5, LEFT, BIOPSY:

1. Benign lymph node
2. No evidence of metastatic carcinoma

Final TNM: pT1bN0M0

stage: IA

MACROSCOPIC

SPECIMEN TYPE

Wedge resection

TUMOR SITE

Left Lung-Lower Lobe

TUMOR SIZE

2.5 X 2.2 X 1.6 cm

TUMOR FOCALITY

Unifocal

[page 2 of 4]
MICROSCOPIC

HISTOLOGIC TYPE

Papillary adenocarcinoma

HISTOLOGICAL GRADE

G2: (moderately differentiated) of G4

VISCERAL PLEURAL INVASION

Not identified

LYMPHATIC VASCULAR INVASION

Absent

TREATMENT EFFECT

Not applicable

TUMOR EXTENSION

Not applicable

MARGINS

Uninvolved by tumor (Parenchymal)

Distance of tumor from closest margin is 1.5 cm

PATHOLOGIC STAGING

EXTENT OF INVASION

pT1b. [Tumor greater than 2 cm, but 3 cm or less in greatest dimension, surrounded by lung or visceral pleura, without bronchoscopic evidence of invasion more proximal than the lobar bronchus (ie, not in the main bronchus)]

REGIONAL LYMPH NODES

pN0. (No regional lymph node metastasis)

Total nodes: 6

Total positive nodes: 0

N1 nodes: 2

N1 positive nodes: 0

N2 nodes: 4

N2 positive nodes: 0

N2 sites sampled:

Station 9: Pulmonary ligament nodes

Station 7: Subcarinal nodes

Station 5: Subaortic nodes (aorto-pulmonary window)

DISTANT METASTASIS

pM0. (No distant metastasis)

PATHOLOGIC STAGE Summary

Final TNM: pT1bN0M0

stage: IA

** The pathologic stage presumes no distant metastasis.

LUNG ANCILLARY TESTING PROTOCOL

Case number: Patient name:

HISTOLOGIC TYPE

Papillary adenocarcinoma

STAGE IV STATUS

Stage IV status is undetermined

TISSUE BLOCK AVAILABLE FOR ANCILLARY TESTING

C5

COMMENT

This patient's sample does not meet criteria* for reflex EGFR and ALK testing. No fresh tissue is available for ancillary testing. The block identified above will be stored in pathology for 10 years for possible future ancillary testing. Please call for any ancillary testing requests.

EGFR and ALK reflex testing criteria:
Stage IV disease (histologically proven or clinically suspicious)

[page 3 of 4]
[REDACTED]

Adenocarcinoma or TTF-1 positive adenosquamous cell carcinoma. [REDACTED]

Attending Pathologist: [REDACTED]
[REDACTED]

CLINICAL INFORMATION

Lung cancer

SPECIMEN/GROSS DESCRIPTION

A) SOURCE: Lymph node biopsy, level 9, left

The specimen is received labeled "level 9 lymph node (left)," received in formalin, is a 0.8 cm red-black partially yellow and fatty thin lymph node. Submitted in toto in one cassette.

B) SOURCE: Lymph node biopsy, level 9, left, additional tissue

The specimen is received labeled "additional level 9 lymph node (left)." It consists of a 1.2 cm gray-black lymph node. Longitudinally bisected and entirely submitted in one cassette.

C) SOURCE: Lung wedge resection -frozen section, left lower lobe

The specimen is received labeled "wedge resection, left lower lobe." It consists of a 48-gram, 9 x 4.5 x 3 cm lung wedge resection with two partially intersecting staple lines (9.5 x 0.5 cm) in aggregate. The visceral pleural red-tan surfaces include a minimal amount of subpleural anthracosis. The stapled margin is trimmed and immediately subjacent tissue inked black. The intact smooth pleural surfaces are inked green. Cut surfaces disclose a solid firm gray-tan tumor mass, measuring 2.5 x 2.2 x 1.6 cm, 1.5 cm from the black-inked stapled resection margin and 0.2 cm from the green-inked smooth pleural surface.

A representative section of the tumor mass is submitted on one block for frozen microscopy.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Adenocarcinoma, margin negative. Approximately 2.5 cm tumor, approximately 1.5 cm from margin." is rendered by [REDACTED]

The remaining lung parenchyma discloses diffuse mild emphysematous change and a single black peribronchial, 0.3 cm lymph node without evidence of gross tumor.

Note: Fresh tumor is retained for additional possible ancillary studies.

Representative sections are submitted in eight cassettes as follows:

1. Frozen section residue
- 2-3. Stapled resection margin, perpendicular to black ink
- 4-6. Tumor with green-inked pleural surface
7. Normal lung, at least 1.5 cm away from tumor
8. One peribronchial lymph node

Note: The specimen is placed in formalin at approximately [REDACTED] on [REDACTED] for a minimum of six hours fixation.

This case is accessioned in [REDACTED]
[REDACTED]

D) SOURCE: Left upper lobe wedge resection lung

Labeled "left upper lobe wedge resection lung" received in formalin is a 10.5 x 5 x 4 cm, 55 gram lung wedge. The pleural surface is purple-pink

[REDACTED]

[page 4 of 4]
[REDACTED]

focally ragged with a staple line present along one edge. The staple line is removed from underlying tissues inked green. The lung is serially sectioned revealing a 4 x 3 x 3 cm air pocket surrounded by white-tan dense tissue. The remaining lung parenchyma is red-tan hemorrhagic and spongy without masses or lesions identified. Representative sections are submitted in five cassettes.

E) SOURCE: Level 7 lymph node, left
Labeled "level 7 lymph node, left" is a 0.8 cm red-brown rubbery lymph node. The specimen is entirely submitted in one cassette.

F) SOURCE: Level 5 lymph node, left
Labeled "level 5 lymph node, left" is a 0.6 cm anthracotic lymph node. The specimen is submitted in toto in one cassette.

Gross dictation by: [REDACTED]

MICROSCOPIC

A-F) The microscopic appearance substantiates the diagnosis.

Dictation by: [REDACTED] Scribed by: [REDACTED]

[REDACTED]

COLLECTED: [REDACTED] ACCESSIONED [REDACTED] SIGNED: [REDACTED]

Lab and Collection

GROSS AND MICROSCOPIC SURGICAL PANEL [REDACTED] - Lab and Collection Information

Result History

GROSS AND MICROSCOPIC SURGICAL PANEL [REDACTED] Order Result History Report.

Lab Status

Order Complete [3]

Result Information

Result Date and Time	Status	Provider Status
[REDACTED]	Final result	Ordered

Lab Information

Lab

[REDACTED]

Order Details

Parent Order ID	Child Order ID
[REDACTED]	[REDACTED]

Entry Date

[REDACTED]

Specimen Information

Specimen Source	Collection Date	Collection Time
Lung	[REDACTED]	[REDACTED]

Audit Trail

[REDACTED]

Source: NCI Genomic Data Commons file 1b7d5087-fb69-4335-b908-518c85aff944 (TCGA-55-8085.16F4298E-D5F3-4503-BDAD-A15531C3635C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).